CTSP case CTSP-ACZW — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1897c9a8-d44e-4777-8cf5-322df09f589b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1939; Vital status: Dead; Days to death: 918 days (2.5 years); Year of death: 2011; Cause of death: Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 68.9 years (25,168 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Days to last follow up: 918 days (2.5 years); Best overall response: Complete Response; Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): High-Intermediate Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 94 kg; Height: 178 cm; BMI: 29.7.

Biospecimens (1 sample)
- Sample DLBCL11328-sample: Sample type: Tumor; Tissue type: Tumor.
